Gene-level copy-number profile of tumor specimen TCGA-34-8454-01A from TCGA case TCGA-34-8454, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.7 years (22,913 days).
Specimen TCGA-34-8454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.28abcff6-98dc-47a6-8895-7bd5b9125588.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-8454-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd529349-67cd-43f0-88d2-686106a17ec7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 11,383; copy number 2: 44,206; copy number 3: 2,569; copy number 4: 1,370; copy number 5: 205.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-8454-01A-11D-2322-01): tumor purity 0.45, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–23,682,662, 82 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 205 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:71,719,275–74,103,216, 49 genes, copy number 5: CARTPT, AC143336.1, AC025774.1, MAP1B, MIR4803, MRPS27, RN7SL153P, PTCD2, AC093278.1, YBX1P5, AC093278.2, ZNF366, LINC02056, AC063979.1, RPL7P22, H2BL1P, Y_RNA, AC035140.1, TNPO1, MIR4804, RPL35AP13, AC008972.1, AC008972.2, FCHO2, AC020893.1, CHP1P1, TMEM171, AC116345.3, AC116345.2, TMEM174, AC116345.4, AC116345.1, LINC02230, AC099522.1, FOXD1, FOXD1-AS1, LINC01385, LINC01386, AC099522.2, BTF3, FUNDC2P1, ANKRA2, UTP15, ARHGEF28, AC091868.2, AC091868.1, RNU7-196P, AC093283.1, LINC02122.
- chr8:41,261,962–50,860,062, 156 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,571. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
